CCDI case PBCNLG — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/b9e64e1a-f3b4-4e77-99ab-917f8b1dfb97

Demographics
Sex at birth: male; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Pilocytic astrocytoma: ICD-O-3 morphology code: 9421/1; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 5.0 years (1,828 days).

Biospecimens (3 samples)
- Sample 0DVXF8: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DVXFA: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DVXFS: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
